Somatic mutation profile of tumor specimen 0DNGGP from CCDI case PBCBMD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 17.7 years (6,454 days).
Specimen 0DNGGP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f9d8cc9-41f8-4ed5-8981-61dd4a30ba83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNGG9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3430e4e2-88b6-4ac1-8ba1-3923776a3a7b

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 5, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.14395C>T p.R4799* (on ENST00000591111; = p.R3872* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 251/852 reads (29%) | catalogued as rs1057518470, COSV59932123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 29/914 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CDH10 | c.1843A>T p.I615F | Missense Mutation (SNP) | VAF 209/784 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CHD9 | c.1503G>T p.Q501H | Missense Mutation (SNP) | VAF 378/1101 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CNFN | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COMMD5 | c.402del p.Q134Hfs*28 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, varscan2
- KANSL1 | c.2815C>A p.P939T (on ENST00000574590 / NM_001193465.2; = p.P940T on NM_015443.4) | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PGBD1 | c.1666G>C p.D556H | Missense Mutation (SNP) | VAF 162/498 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PGBD1 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 157/439 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HYDIN | c.6372C>T p.D2124= | Silent (SNP) | VAF 110/394 reads (28%) | catalogued as COSV59253393; called by muse, mutect2, varscan2
- AKNA | c.*53C>T | 3'UTR (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 20/134 reads (15%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 19/129 reads (15%) | called by muse, varscan2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 7/74 reads (9%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 7/73 reads (10%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 24/226 reads (11%) | called by muse, varscan2
